Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7797, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7797-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Prostate cancer.
PROCEDURE: Radical prostatectomy.
SPECIFIC CLINICAL QUESTION: Not stated.
OUTSIDE TISSUE DIAGNOSIS: Not stated.
PRIOR MALIGNANCY: Not stated.
CHEMORADIATION: Not stated.
ORGAN TRANSPLANT: Not stated.
IMMUNOSUPPRESSION: Not stated.
OTHER DISEASES: Not stated.

FINAL DIAGNOSIS:

PART1: LYMPH NODE, RIGHT PELVIC, EXCISION –
EIGHT BENIGN LYMPH NODES (0/8).

PART2: LYMPH NODE, LEFT PELVIC, EXCISION –
SIX BENIGN LYMPH NODES (0/6).

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY –

- A. PROSTATE ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 3 + 4 = 7.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.4 CM IN ONE HISTOLOGIC SECTION.
- C. THE CARCINOMA INVOLVES LESS THAN 5% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- G. NO PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT2c N0 Mx.
- K. BACKGROUND PROSTATE TISSUE WITH NODULAR HYPERPLASIA AND CHRONIC AND ACUTE INFLAMMATION.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 5.4
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	20%
WEIGHT OF PROSTATE:	73.85gm
TUMOR SIZE:	Maximum dimension: 1.4 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	< 5% of specimen involved by invasive tumor
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - NOS
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	No
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	14
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMx
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file e16b81fc-3a98-484e-a7cf-6eca350af4da (TCGA-EJ-7797.D9D6F871-C436-469E-9D7F-9684C379A320.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).